Gene-level copy-number profile of tumor specimen TCGA-XV-A9W2-01A from TCGA case TCGA-XV-A9W2, project TCGA-SKCM (Skin Cutaneous Melanoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Malignant melanoma, NOS; Tissue or organ of origin: Skin, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 81.7 years (29,836 days).
Specimen TCGA-XV-A9W2-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-SKCM.61525dc5-b2e7-415b-9224-6f0230e82f95.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-XV-A9W2-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 807 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/bdc9a5e8-54c6-4c4d-87ae-4536688b1597

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 2; copy number 1: 17; copy number 2: 11,397; copy number 3: 13,321; copy number 4: 25,792; copy number 5: 3,714; copy number 6: 2,221; copy number 7: 704; copy number 8: 473; copy number 9: 1,799; copy number 10: 3; copy number 11: 24; copy number 12: 122; copy number 13: 122; copy number 17: 41; copy number 18: 64.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-XV-A9W2-01A-11D-A396-01): tumor purity 0.54, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,175 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:19,143,695–26,546,933, 164 genes, copy number 9 (broad region; genes not listed).
- chr7:25,948,657–26,647,305, 15 genes, copy number 9: AC010719.1, MIR148A, NFE2L3, HNRNPA2B1, CBX3, AC010677.2, AC010677.1, SNX10, AC004540.2, AC004540.1, KIAA0087, AC004947.2, AC004947.1, AC004947.3, LINC02860.
- chr7:93,424,486–93,574,730, 3 genes, copy number 10 (within-gene range 4–10): CALCR, MIR653, MIR489.
- chr8:46,579,213–114,791,929, 1,025 genes, copy number 9 (within-gene range 4–9) (broad region; genes not listed).
- chr8:115,950,511–145,066,685, 505 genes, copy number 9 (broad region; genes not listed).
- chr11:68,460,731–71,639,769, 85 genes, copy number 9–13 (within-gene range 7–13) (broad region; genes not listed).
- chr11:76,349,956–79,989,630, 73 genes, copy number 11–18 (broad region; genes not listed).
- chr22:20,318,119–21,192,156, 55 genes, copy number 12: AC007663.4, AC007663.3, FAM230G, AC007731.2, AC007731.5, USP41, ZNF74, RNU6-225P, SCARF2, AC007731.4, KLHL22, AC007731.1, RNY1P9, Y_RNA, RN7SL812P, KRT18P5, MED15, AC007731.3, CCDC74BP1, SMPD4P1, IGLL4P, SLC9A3P2, ABHD17AP4, POM121L4P, BCRP5, TMEM191A, PI4KA, SERPIND1, SNAP29, AC007308.1, CRKL, LINC01637, AIFM3, AC002470.2, AC002470.1, LZTR1, THAP7, THAP7-AS1, AC002472.2, TUBA3FP, P2RX6, AC002472.3, SLC7A4, AC002472.1, MIR649, P2RX6P, LRRC74B, TUBA3GP, AC002472.4, BCRP2, AP000550.1, POM121L7P, E2F6P2, FAM230B, AP000550.2.
- chr22:25,561,117–26,383,597, 15 genes, copy number 11 (within-gene range 7–11): AL022329.1, GRK3, AL022329.2, YES1P1, RNA5SP494, MYO18B, AL022329.3, MYO18B-AS1, Z98949.2, RN7SKP169, Z98949.1, LINC02559, AL022337.1, SEZ6L, SEZ6L-AS1.
- chr22:37,830,855–38,318,084, 29 genes, copy number 13 (within-gene range 7–13): ANKRD54, MIR658, MIR659, EIF3L, AL022311.1, RNU6-900P, MICALL1, AL031587.5, C22orf23, AL031587.3, POLR2F, MIR6820, SOX10, MIR4534, AL031587.1, AL031587.4, PICK1, AL031587.2, SLC16A8, BAIAP2L2, AL022322.1, PLA2G6, AL022322.2, MAFF, TMEM184B, AL020993.1, RN7SL704P, Metazoa_SRP, CSNK1E.
- chr22:40,410,281–40,636,719, 1 gene, copy number 12 (within-gene range 7–12): MRTFA.
- chr22:40,521,800–47,261,007, 205 genes, copy number 9–17 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 10. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
